Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1MI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1MI-01A (Primary Tumor).

1CD-0-3
Carcinoma, Squamous cell, NOS 8070/3
Site: cervix, NOS C53.9 2/24/11 JW

SURGICAL PATHOLOGY REPORT - CONSULT FINAL

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED]

Service: Inside/Outside
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

DIAGNOSIS

UTERUS, CERVIX #1, BIOPSY (OSC [REDACTED] AND B, [REDACTED])
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

UTERUS, CERVIX #2, BIOPSY (C)
- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

UTERUS, CERVIX #3, BIOPSY (D)
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

UTERUS, CERVIX #4, BIOPSY (E)
- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

UTERUS, ENDOCERVIX, CURETTAGE (F)
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

No	Yes
☒	☐
Criteria	
UPAA Discrepancy	
Not Malignancy History	
Not Synchronous Primary	
See is (circle):	

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

***Report Electronically Reviewed and Signed Out By

Microscopic Description and Comment

The depth of invasion cannot be assessed from these biopsies. No lymphovascular space invasion is identified.

M.D.

History

The patient is a [REDACTED] year old female with HGSIL on Pap [REDACTED], and a large lesion on the anterior cervix.

Material(s) Received

Received are six slides labeled [REDACTED], accompanied by a corresponding pathology report. The material

Source: NCI Genomic Data Commons file 71f98050-068d-4ff9-bbed-aa1ff1d59133 (TCGA-C5-A1MI.FD31F805-C852-467E-9708-7D00339944B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).